Somatic mutation profile of tumor specimen TCGA-E8-A2JQ-01A (aliquot TCGA-E8-A2JQ-01A-11D-A19J-08) from TCGA case TCGA-E8-A2JQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 18.3 years (6,684 days).
Specimen TCGA-E8-A2JQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21540c0a-2ccc-449e-b413-4c8fc617b9d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A2JQ-10A (Blood Derived Normal), aliquot TCGA-E8-A2JQ-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cb26f44-d587-4451-96c2-293a10282e0a

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AKR1D1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99653120; called by muse, mutect2
- CHAF1B | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100023600; called by muse, mutect2, varscan2
- DOCK8 | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.066); catalogued as COSV101209953; called by muse, mutect2
- FAM78A | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV99908546; called by muse, mutect2
- FAM98C | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV99385020; called by muse, mutect2
- FPR1 | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV100494122; called by muse, mutect2
- GPSM3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769669212, COSV100900727; called by muse, mutect2
- HECW2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV99647475; called by muse, mutect2
- NES | c.1145C>T p.T382I | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs1450759940, COSV100958026; called by muse, mutect2
- NEXMIF | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99282173; called by muse, mutect2
- PLCB4 | c.3311A>G p.E1104G | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV99595768; called by muse, mutect2, varscan2
- RLIM | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.312); catalogued as COSV100223066; called by muse, mutect2
- TANC1 | c.5208G>C p.Q1736H | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV99714184; called by muse, mutect2
- TCP11L2 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100135421; called by muse, mutect2
- TENM1 | c.3661C>T p.P1221S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs868670043, COSV64449169; called by muse, mutect2
- TLR8 | c.2970G>C p.L990F (on ENST00000218032 / NM_138636.5; = p.L1008F on NM_016610.4) | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV99487077; called by muse, mutect2
- NCOR2 | c.5556C>T p.S1852= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV62295244; called by muse, mutect2
- PPP1R3F | c.753G>A p.E251= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99278792; called by muse, mutect2
- TUBB8 | c.534C>T p.T178= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as rs372550049, COSV59117182; called by muse, mutect2, varscan2
